TCGA case TCGA-C5-A1ME — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a0598331-79e1-418d-b50c-fd945b843506

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 40 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 41.0 years (14,970 days); Year of diagnosis: 2003; Method of diagnosis: Biopsy; AJCC pathologic T: T1b1; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IB1; FIGO staging edition year: 1995; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,756 days (4.8 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 27; Lymphatic invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 69 (prior to adjuvant therapy): ECOG performance status: 0.
- Days to follow up: 132 days; Disease response: Tumor Free.
- Days to follow up: 1,756 days (4.8 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Human Papillomavirus: Positive [Hpv strain: HPV16].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Comorbidities: Human Papillomavirus Infection; Risk factors: Human Papillomavirus Infection.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Initial Diagnosis; Weight: 69 kg; Height: 165 cm; BMI: 25.3.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 22; Tobacco smoking quit year: 2003; Age at onset: 18.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A1ME-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-C5-A1ME-01A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 5.
- Sample TCGA-C5-A1ME-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A1ME-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 1; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 1; Tobacco smoking history indicator: 4; Submitted tumor site: Cervical; Histologic diagnosis: Endocervical Type of Adenocarcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Margins involved hysterectomy: Other Location, specify; Other involved margins: margins free of tumor; Lymph nodes examined: Yes; Lymphovascular invasion: Absent; Corpus involvement: Absent; Days to ct scan ab pelvis: 13.
- Human papillomavirus types: HPV types positive: HPV 16.
- Follow-up form: Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; Radiation adjuvant indicator: No; Radiation treatment reason not completed: Not done per treating physician discretion; New tumor event diagnosis indicator: No.
- Follow-up form, Radiation supplemental: Chemo concurrent reason not given: Not done per treating physicians discretion.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,756 days; disease-specific survival: no event (censored), 1,756 days; disease-free interval: no event (censored), 1,756 days; progression-free interval: no event (censored), 1,756 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A1ME-01A-11D-A13V-01): tumor purity 0.73, ploidy 2.94, whole-genome doublings 1.
